Gene-level copy-number profile of tumor specimen TCGA-MP-A4TI-01A from TCGA case TCGA-MP-A4TI, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.7 years (26,565 days).
Specimen TCGA-MP-A4TI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.147ff92e-a68a-4453-a1cb-132ac06ff511.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MP-A4TI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0d7fec54-4569-4c0b-bfbb-a2f25057a6cb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,870; copy number 2: 44,277; copy number 3: 6,945; copy number 4: 1,346; copy number 5: 377; copy number 7: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MP-A4TI-01A-21D-A24O-01): tumor purity 0.22, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 381 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,305,491–209,114,419, 160 genes, copy number 5 (broad region; genes not listed).
- chr8:123,178,960–128,564,679, 109 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr12:57,253,762–63,360,037, 112 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,956. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
